TARGET case TARGET-10-PARRPK — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/96aa014e-1ecb-5ec5-926e-40f42a34351e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 24 years; Vital status: Dead; Days to death: 2,817 days (7.7 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 24.4 years (8,898 days); Year of diagnosis: 2007; Days to last follow up: 2,817 days (7.7 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (2 entries)
- Days to follow up: 2,587 days (7.1 years); Days to first event: 2,587 days (7.1 years); First event: Relapse.
- Days to follow up: 2,817 days (7.7 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2015.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 172 ×10³/µL.
- Day 8: Bone Marrow blast count 87%; Minimal Residual Disease (Flow Cytometry) 32.5%.
- Day 15: Bone Marrow blast count 22%.
- Day 29: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 1.1%.
- Day 43: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 0.24%.
- Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (3 samples)
- Sample TARGET-10-PARRPK-09B: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARRPK-14B: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARRPK-60.1C: Sample type: Primary Xenograft Tissue; Tissue type: Tumor; Tumor descriptor: Xenograft.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Xenografts_20230727.xlsx:
- Overall Survival Time in Days: 2817
- WBC at Diagnosis: 172
- CNS Status at Diagnosis: CNS 2a
- Testicular Involvement: No
- MRD Day 8: 32.5
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 1.1
- MRD Day 29 Sensitivity: 0.01
- MRD Day 43: 0.24
- MRD End Consolidation: 0
- MRD End Consolidation Sensitivity: 0
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 87
- BMA Blasts Day 15: 22
- BMA Blasts Day 29: 0
- BMA Blasts Day 43: 0
- Karyotype: 46,XY,add(1)(q42)[3]/46,idem,del(9)(p21),add(14)(p11.2)[14]/46,XY[2]
- Down Syndrome: No
- DNA Index: 1
- Alternate Therapy: Chemotherapy; Radiation (NOS); Transplant
- Cell of Origin: B Cell ALL
